Gene-level copy-number profile of tumor specimen HCM-CSHL-0240-C18-01A from HCMI case HCM-CSHL-0240-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 81.9 years (29,899 days).
Specimen HCM-CSHL-0240-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 464675aa-22c8-4427-82cb-e9b8d340d79b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0240-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/81833321-513c-4bff-bdff-7c219b8ceb6b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,131; copy number 2: 54,202; copy number 3: 3,059.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:91,108,023–91,112,790, 1 gene (within-gene range 0–2): AC004054.1.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–1): RNU6-457P.
- chr16:32,475,051–32,478,250, 1 gene: ABCD1P3.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–2): AL138808.1.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,018. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
